Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A962, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A962-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

tumor: 5.0 x 5.0 x 4.0 cm

Diagnosis:

Type A-Thymoma

pT2, pN0 (0/4)

Masaoka: II.2

focal infiltration of mediastinal fat tissue

Immunohistochemistry

epithelial cells positive for: KL1

epithelial cells negative for: CD1a, CD5, CD117

in between epithelial cells some CD1a-positive immature T-lymphocytes

ICD O-3
Thymoma, type A
malignant 8581/3
Site Anterior mediastinum
(38.1)
4/17/14

Source: NCI Genomic Data Commons file 82ec6c10-2f4c-4f13-85c5-c366c7576777 (TCGA-ZB-A962.6A36C52D-715D-41BA-972A-205C690CAFAF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).